Gene-level copy-number profile of tumor specimen TCGA-24-2288-01A from TCGA case TCGA-24-2288, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 70.7 years (25,831 days).
Specimen TCGA-24-2288-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.c5ca843c-5bcf-4d73-adba-4c40036f1c67.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-2288-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9d7884a0-7bba-4112-9839-63eb73793e1d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 79; copy number 2: 2,310; copy number 3: 20,123; copy number 4: 10,495; copy number 5: 14,250; copy number 6: 8,942; copy number 7: 924; copy number 8: 2,268; copy number 9: 169; copy number 10: 78; copy number 11: 58; copy number 12: 91; copy number 13: 12; copy number 15: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-2288-01A-01D-0704-01): tumor purity 0.52, ploidy 4.47, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 79 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:25,377,198–25,673,647, 1 gene (within-gene range 0–3): DTNB.
- chr2:25,697,076–26,290,465, 19 genes (within-gene range 0–3): Y_RNA, ASXL2, TPM3P7, PTGES3P2, AC064847.1, NDUFB4P4, KIF3C, UQCRHP2, TRMT112P6, RAB10, RNU6-942P, RPS2P15, EMP2P1, SMARCE1P6, AC011742.1, PPIL1P1, GAREM2, HADHA, HADHB.
- chr4:19,455,418–19,938,448, 3 genes (within-gene range 0–5): AC024230.1, AC110767.1, AC114728.1.
- chr4:27,585,145–36,426,428, 55 genes: IGBP1P5, AC007106.2, AC007106.1, AC093791.2, AC093791.1, AC097480.1, AC097480.2, RN7SL101P, MIR4275, MESTP3, LINC02364, AC068944.2, AC068944.1, AC109349.1, LINC02472, AC092593.2, AC092593.1, U6, EEF1A1P21, AC097510.1, RPS3AP17, AC106868.1, AC098595.1, PCDH7, AC097716.1, MTCYBP43, LINC02497, AC104071.1, LINC02501, LINC02506, AC097654.1, LINC02353, AC116611.1, MAPRE1P2, AC093606.1, AC093878.1, AC097535.2, AC097535.1, AC079772.1, AC016687.3, AC016687.2, AC016687.1, LINC02484, AC110790.1, AC093689.1, AC093913.1, AC020589.1, SEC63P2, RNU6-573P, ARAP2, AC098827.1, AC104078.1, DTHD1, AC104078.2, MIR1255B1.
- chr4:36,506,043–36,508,869, 1 gene: AC125336.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,607 genes in 50 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:53,180,921–53,889,798, 24 genes, copy number 8: AL606760.4, CPT2, AL606760.2, CZIB, AL606760.3, MAGOH, AL606760.1, LRP8, AL355483.3, AL355483.1, AL355483.2, LINC01771, AC119428.2, AC119428.1, LINC02812, SLC25A3P1, AL365445.1, DMRTB1, GLIS1, RNU7-95P, NDC1, AL049745.1, AL049745.2, YIPF1.
- chr1:63,774,017–64,833,232, 12 genes, copy number 8: ROR1, AL161742.1, CFL1P3, RNU6-809P, Y_RNA, ROR1-AS1, AL445205.1, UBE2U, RNU7-62P, CACHD1, MIR4794, RAVER2.
- chr1:171,781,660–173,489,407, 29 genes, copy number 7: EEF1AKNMT, AL031864.1, AL031864.2, DNM3, DNM3-IT1, DNM3OS, MIR214, MIR3120, MIR199A2, AL137157.1, RNU6-157P, PIGC, C1orf105, SUCO, RNU6-693P, FASLG, SLC25A38P1, Z98043.1, AL031599.1, AIMP1P2, Z97198.1, TNFSF18, GOT2P2, AL022310.1, TNFSF4, AL645568.2, AL645568.1, PRDX6-AS1, PRDX6.
- chr2:28,683,976–30,820,542, 35 genes, copy number 7: RNA5SP89, AC092164.1, PPP1CB, SPDYA, AC097724.1, TRMT61B, WDR43, SNORD92, SNORD53, Y_RNA, SNORD53B, TOGARAM2, Y_RNA, PCARE, AC105398.1, CLIP4, ALK, AC074096.1, RN7SL516P, AC106870.3, AC106870.2, AC106870.1, AC016907.2, AC016907.1, YPEL5, SNORA10B, H3P5, LBH, AC109642.1, LINC01936, AC073255.1, LCLAT1, AC132154.1, CAPN13, AC092569.1.
- chr2:237,324,003–242,160,153, 138 genes, copy number 8 (broad region; genes not listed).
- chr3:66,133,610–67,011,210, 10 genes, copy number 9: SLC25A26, RNU6-787P, RN7SL482P, LRIG1, AC104440.1, RPL21P41, AC098969.2, AC098969.1, AC020655.1, KBTBD8.
- chr3:112,561,709–170,305,977, 998 genes, copy number 7–8 (broad region; genes not listed).
- chr3:170,357,678–177,228,000, 82 genes, copy number 8–9 (within-gene range 2–9) (broad region; genes not listed).
- chr3:177,294,442–184,780,720, 172 genes, copy number 8 (broad region; genes not listed).
- chr4:49,561,285–52,551,574, 15 genes, copy number 7 (within-gene range 3–7): AC119751.6, SNX18P24, AC119751.4, SNX18P25, DCUN1D4, DUTP7, AC027271.1, AC104784.1, LRRC66, SGCB, LINC02480, SPATA18, AC097522.2, AC097522.1, RNU6-1252P.
- chr5:133,025,847–133,612,541, 11 genes, copy number 9 (within-gene range 6–9): AC113410.5, AC113410.4, HSPA4, AC113410.3, AC113410.2, AC010307.2, AC010307.1, FSTL4, AC010307.3, AC010307.4, AC010608.1.
- chr6:12,319,453–12,585,404, 4 genes, copy number 8: SUMO2P12, RN7SKP293, RPL15P3, LINC02530.
- chr6:33,694,293–33,927,631, 10 genes, copy number 9 (within-gene range 5–9): UQCC2, MIR3934, IP6K3, LEMD2, MLN, AL138889.3, LINC01016, AL138889.2, AL138889.1, MIR7159.
- chr6:106,570,771–106,975,627, 9 genes, copy number 7: RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24.
- chr6:154,387,515–155,257,723, 15 genes, copy number 8 (within-gene range 4–8): CNKSR3, AL357075.2, AL357075.3, AL357075.1, MTRES1P1, RPS4XP8, AL591419.1, AL591499.1, SCAF8, RNU6-824P, TIAM2, AL121952.1, MIR1273C, U8, AL136228.1.
- chr7:6,161,776–6,551,436, 10 genes, copy number 13 (within-gene range 5–13): CYTH3, Y_RNA, FAM220A, AC009412.1, RPSAP73, RAC1, DAGLB, KDELR2, AC072052.1, GRID2IP.
- chr7:40,538,127–43,869,893, 32 genes, copy number 9: SUGCT-AS1, AC005160.1, LINC01450, LINC01449, INHBA, INHBA-AS1, GLI3, HMGN2P30, LINC01448, TCP1P1, AC010132.1, AC010132.4, C7orf25, AC010132.3, PSMA2, AC010132.2, MRPL32, AC005537.1, Y_RNA, HECW1, HECW1-IT1, MIR3943, RNU7-35P, RNU6-575P, AC004692.2, AC004692.1, LUARIS, STK17A, COA1, BLVRA, AC005189.1, MRPS24.
- chr7:47,608,465–47,979,615, 7 genes, copy number 8 (within-gene range 5–8): LINC01447, C7orf65, PKD1L1, LINC00525, C7orf69, AC069282.1, HUS1.
- chr7:70,837,738–73,358,637, 49 genes, copy number 10: AC073873.1, GALNT17, MIR3914-1, MIR3914-2, RN7SKP75, CALN1, RNA5SP232, AC005011.1, ABCF2P2, TYW1B, MIR4650-2, AC211469.2, AC211469.1, RN7SL377P, SBDSP1, RN7SL625P, SPDYE7P, POM121, AC211476.2, NSUN5P2, AC211476.6, TRIM74, STAG3L3, AC211476.1, Y_RNA, PMS2P7, Y_RNA, SPDYE8, PMS2P8, Y_RNA, AC211476.5, AC211476.3, SPDYE11, AC211476.4, Y_RNA, SPDYE9, PMS2P6, Y_RNA, SPDYE10P, GTF2IP4, PHBP5, NCF1B, GTF2IRD2P1, POM121B, NSUN5, TRIM50, AC211485.1, FKBP6, RNU6-1080P.
- chr8:110,334,743–118,111,826, 49 genes, copy number 7: AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, AC022360.1, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2, AC055788.1, AC103993.1, Y_RNA, AC064802.1, AC025881.1, CARS1P2, TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16, EXT1.
- chr8:119,873,717–128,564,679, 143 genes, copy number 7 (broad region; genes not listed).
- chr8:141,207,166–141,518,737, 17 genes, copy number 8: SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3, MROH5, AC100803.4, AC100803.1, HNRNPA1P38, AC138647.2, AC138647.1.
- chr9:78,150,532–83,707,958, 62 genes, copy number 7–9 (within-gene range 3–9) (broad region; genes not listed).
- chr9:86,944,362–87,260,585, 7 genes, copy number 9: GAS1, GAS1RR, AL513318.1, CDC20P1, NFYCP2, LINC02872, AL136367.1.
- chr9:124,001,670–124,033,301, 4 genes, copy number 10: LHX2, AC006450.3, AC006450.1, AC006450.2.
- chr10:44,712–23,194,245, 396 genes, copy number 8–12 (broad region; genes not listed).
- chr10:73,730,562–77,966,440, 84 genes, copy number 7–15 (broad region; genes not listed).
- chr11:69,294,151–69,444,743, 6 genes, copy number 8: MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1.
- chr11:121,238,304–121,633,763, 7 genes, copy number 7 (within-gene range 4–7): AP001124.1, RPS4XP12, SC5D, BMPR1AP2, AP002365.1, AP000977.1, SORL1.
- chr12:66,767–32,993,754, 832 genes, copy number 8–12 (broad region; genes not listed).
- chr14:35,278,633–35,447,625, 6 genes, copy number 7: PSMA6, AL133163.2, AL133163.1, NFKBIA, DNAJC8P1, AL133163.3.
- chr14:88,819,608–89,111,223, 6 genes, copy number 8: AL121768.1, RNU4-92P, TTC8, Y_RNA, AL137785.1, MPPE1P1.
- chr16:53,991,012–59,755,026, 170 genes, copy number 7 (broad region; genes not listed).
- chr17:31,830,731–32,997,877, 54 genes, copy number 7: AC004253.2, COPRS, UTP6, AC004253.1, SUZ12, RNA5SP437, AC090616.3, LRRC37B, AC090616.4, SH3GL1P1, AC090616.6, AC090616.2, AC090616.5, AC090616.1, WDR45BP1, AC116407.2, AC116407.1, RHOT1, ARGFXP2, AC116407.4, AC116407.3, UBL5P2, AC026620.2, RHBDL3, AC026620.1, AC005899.4, C17orf75, AC005899.3, OOSP1P2, MIR632, ZNF207, AC005899.6, AC005899.7, AC005899.5, AC005899.8, AC005899.1, AC005899.2, PSMD11, Y_RNA, CDK5R1, MYO1D, AC079336.5, AC079336.7, AC079336.2, AC079336.1, AC079336.6, AC079336.4, AC079336.3, AC025211.1, Y_RNA, AC084809.1, AC084809.2, TMEM98, SPACA3.
- chr19:58,126,248–58,216,561, 6 genes, copy number 11–13 (within-gene range 4–13): ZNF329, AC008751.1, AC008751.3, AC008751.2, ZNF274, RPS15AP36.
- chr20:37,676,889–38,033,461, 5 genes, copy number 11: AL162293.1, CTNNBL1, VSTM2L, RN7SKP185, TTI1.
- chr20:50,118,254–50,321,342, 9 genes, copy number 9: PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON, LINC01270, LINC01271.
- chr20:57,168,753–57,409,333, 12 genes, copy number 8 (within-gene range 6–8): BMP7, BMP7-AS1, AL122058.1, Y_RNA, MIR4325, RPL39P39, SPO11, RAE1, MTND1P9, MTRNR2L3, RBM38-AS1, RBM38.
- chr21:14,918,534–15,627,342, 13 genes, copy number 8 (within-gene range 4–8): AF127577.3, NRIP1, AF127577.1, AF127577.2, AF127577.6, AF127577.5, AF222684.1, AF222685.1, AF130248.1, AF246928.1, AJ009632.2, CYCSP42, AJ009632.1.
- chr22:45,604,432–47,487,111, 42 genes, copy number 7: LINC01589, RNU6-1161P, Z95331.1, ATXN10, MIR4762, Z84478.1, BX324167.2, BX324167.1, WNT7B, BX537318.2, BX537318.1, LINC00899, PRR34, AL121672.3, PRR34-AS1, MIRLET7BHG, AL121672.1, AL121672.2, MIR3619, MIRLET7A3, MIR4763, MIRLET7B, PPARA, FP325332.1, CDPF1, PKDREJ, TTC38, GTSE1-DT, GTSE1, TRMU, CELSR1, AL031597.1, AL021392.1, GRAMD4, CERK, AL118516.1, TBC1D22A, TBC1D22A-AS1, FP325331.1, Z83836.1, Z82186.1, LINC01644.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
